Gene-level copy-number profile of tumor specimen TCGA-3A-A9IO-01A from TCGA case TCGA-3A-A9IO, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Body of pancreas; Tumor grade: G1; Age at diagnosis: 56.0 years (20,451 days).
Specimen TCGA-3A-A9IO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.3d8b5d8f-2b9d-4d8c-8391-277e8228ba95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3A-A9IO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5c05796-a20c-4f5a-b746-f4d1c2be30df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 5,722; copy number 2: 29,107; copy number 3: 17,452; copy number 4: 7,467; copy number 5: 16; copy number 6: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3A-A9IO-01A-11D-A38F-01): tumor purity 0.7, ploidy 2.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:153,129,074–153,200,017, 4 genes: AC117394.1, AC117394.2, RAP2B, RN7SL300P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:152,374,998–153,223,543, 4 genes, copy number 5 (within-gene range 4–5): AC008571.2, NMUR2, AC008571.1, LINC01470.
- chr5:155,397,291–155,398,353, 1 gene, copy number 6: AC010591.1.
- chr6:39,934,595–40,715,363, 11 genes, copy number 5 (within-gene range 3–5): TUBBP9, FO393411.1, AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1.
- chr7:8,433,609–8,752,961, 1 gene, copy number 5 (within-gene range 3–5): NXPH1.
- chr12:13,044,381–13,982,002, 12 genes, copy number 6 (within-gene range 3–6): FAM234B, GSG1, EMP1, AC022276.1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162.

Autosomal genes at a single copy (total copy number 1): 3,340. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
